Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5099, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5099-01A (Primary Tumor).

FINAL DIAGNOSIS

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE.
- B. THE FUHRMAN'S NUCLEAR GRADE IS III/ IV.
- C. RENAL CELL CARCINOMA GROWS IN ACINAR PATTERN WITH EXTENSIVE INTRATUMORAL HEMORRHAGE
- D. THE GREATEST DIAMETER OF THE NEOPLASM IS 7.0 CM.
- E. THE CARCINOMA EXTENDS INTO THE SOFT TISSUE IN THE REGION OF THE RENAL SINUS.
- F. THE TUMOR IS CONFINED WITHIN THE GEROTA'S FASCIA.
- G. THE CARCINOMA INVADES THE RENAL VEIN WITH LARGE TUMOR THROMBUS IDENTIFIED.
- H. URETERAL AND RENAL VASCULAR MARGINS ARE FREE OF CARCINOMA.
- I. THE NON-NEOPLASTIC KIDNEY SHOWS NEPHROSCLEROSIS.
- J. THE ADRENAL GLAND IS NOT IDENTIFIED.
- K. TNM STAGE: pT3b Nx Mx.
- L. TNM HISTOLOGIC GRADE = G3 (POORLY DIFFERENTIATED).

Source: NCI Genomic Data Commons file 3e00be51-eb0f-4a7d-8ca8-7453f1429df1 (TCGA-B0-5099.075C48DD-A80C-426E-BD91-CA712B479AF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).